Gene-level copy-number profile of tumor specimen TCGA-NP-A5GZ-01A from TCGA case TCGA-NP-A5GZ, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 50.6 years (18,476 days).
Specimen TCGA-NP-A5GZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 98c2e00c-3a7d-4704-a1dd-d4528acc8ed7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-NP-A5GZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/55fd1311-11e0-4944-902f-f95a6dc9bc56

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 53; copy number 1: 21,827; copy number 2: 36,520.

Homozygous deletions (total copy number 0; autosomes only): 53 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr1:144,412,576–145,242,124, 24 genes: RNVU1-15, AC246785.3, AC246785.2, NBPF15, PFN1P6, AC246785.1, RNVU1-26, RNVU1-2A, RNVU1-28, PPIAL4F, LINC01632, FP700111.1, FP700107.1, RNA5SP59, FP700111.2, FP700111.3, SRGAP2B, AC242498.1, FAM72D, LINC01145, RNU1-153P, AC241585.2, AC241585.1, PPIAL4D.
- chr2:130,521,197–130,691,691, 11 genes (within-gene range 0–1): CFC1B, AC013269.1, PRSS40B, PRSS40A, AC140481.2, CFC1, Metazoa_SRP, POTEJ, RNU6-848P, CYP4F30P, AC140481.3.
- chr2:130,692,243–130,693,770, 1 gene (within-gene range 0–1): KLF2P3.
- chr6:29,124,210–29,182,445, 4 genes: AL645937.2, AL645937.1, OR2J2, OR2J4P.
- chr17:46,274,784–46,579,691, 9 genes: ARL17B, LRRC37A, RN7SL656P, NSFP1, RDM1P2, LRRC37A2, ARL17A, RN7SL199P, FAM215B.
- chr18:45,034–73,545, 3 genes: AP001005.1, TUBB8B, AP001005.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 19,483. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
